Gene-level copy-number profile of tumor specimen TCGA-DD-AACF-01A from TCGA case TCGA-DD-AACF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.9 years (25,172 days).
Specimen TCGA-DD-AACF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.66d2434f-400e-4c47-ae49-2ee707905850.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd7a2793-c2a2-4ca2-ac3a-16bd158341d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,903; copy number 2: 42,638; copy number 3: 9,180; copy number 4: 2,519; copy number 5: 577; copy number 7: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACF-01A-11D-A40Q-01): tumor purity 0.9, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 579 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:189,666,149–199,393,307, 100 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–25,267,336, 477 genes, copy number 5 (broad region; genes not listed).
- chr14:27,612,577–27,639,636, 2 genes, copy number 7: LINC00645, MIR3171.

Autosomal genes at a single copy (total copy number 1): 4,903. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
